Somatic mutation profile of tumor specimen BA2366D (aliquot aq-BA2366D) from BEATAML1.0 case 2571, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.8 years (29,879 days).
Specimen BA2366D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5453d788-97e1-4a61-9f69-7d50a54d4a80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3019D (Solid Tissue Normal), aliquot aq-BA3019D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75ff7d66-48f1-42ef-92d0-83f508aba0e1

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, RNA 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C5orf51 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV101068901, COSV67565463; called by muse, mutect2, varscan2
- FLRT2 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV58146304; called by muse, mutect2, varscan2
- GABRQ | c.519C>A p.Y173* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV64782190; called by muse, mutect2
- KIR2DL3 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs1313360099; called by muse, mutect2
- NLRP1 | c.4399G>A p.G1467R (on ENST00000572272 / NM_033004.4; = p.G1423R on NM_014922.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs756213182, COSV52578615; called by muse, mutect2, varscan2
- POPDC2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763822776, COSV51742419; called by muse, mutect2, varscan2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- TNRC6B | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 21/189 reads (11%) | catalogued as rs1191287768, COSV57295243; called by muse, mutect2, varscan2
- TRPC4 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV58997671; called by muse, mutect2, varscan2
- BECN1 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CCN3 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAW1 | c.1189T>A p.Y397N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DHRS2 | c.731+8G>A | Splice Region (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- GCAT | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ITGA7 | c.1529C>T p.A510V (on ENST00000555728; = p.A466V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNC3 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK5 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MGAM2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRB1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SCYL1 | c.2399T>C p.M800T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SOWAHD | c.774C>A p.N258K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2
- SUZ12 | c.1988T>G p.M663R | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- VWF | c.3819C>A p.S1273R | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZBTB33 | c.1109_1119delinsT p.S370Lfs*17 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | called by pindel, varscan2*
- CFAP44 | c.2929C>A p.R977= | Silent (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- CHST8 | c.619C>A p.R207= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV52863290; called by muse, mutect2
- DAPK1 | c.1377C>T p.D459= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs757636093; called by muse, mutect2, varscan2
- DHX30 | c.579G>A p.E193= (on ENST00000445061 / NM_138615.3; = p.E154= on NM_014966.3) | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV62395886; called by muse, mutect2, varscan2
- NOD1 | c.2208C>T p.S736= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs537172994, COSV56111427; called by muse, mutect2, varscan2
- PBRM1 | c.1728C>T p.R576= | Silent (SNP) | VAF 64/255 reads (25%) | called by muse, mutect2, varscan2
- PCK1 | c.114T>C p.C38= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- PRAG1 | c.618C>T p.S206= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs571311964; called by muse, mutect2, varscan2
- SEPTIN4 | c.957A>G p.Q319= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as rs374274766; called by muse, mutect2, varscan2
- TMC1 | c.1605C>T p.T535= | Silent (SNP) | VAF 16/365 reads (4%) | catalogued as rs1281399471, COSV99920783; called by muse, mutect2
- TRIM36 | c.1251A>C p.I417= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- YTHDF2 | c.1476G>A p.K492= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, varscan2
- AIG1 | chr6:143339637 A>G | 3'Flank (SNP) | VAF 39/110 reads (35%) | catalogued as rs749881646; called by muse, mutect2, varscan2
- FAM230F | n.134C>T | RNA (SNP) | VAF 39/213 reads (18%) | called by muse, mutect2, varscan2
- TBC1D3P2 | n.410C>T | RNA (SNP) | VAF 36/110 reads (33%) | catalogued as rs751089279; called by mutect2, varscan2
